Somatic mutation profile of tumor specimen TCGA-B6-A0RI-01A (aliquot TCGA-B6-A0RI-01A-11W-A071-09) from TCGA case TCGA-B6-A0RI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 44.2 years (16,138 days).
Specimen TCGA-B6-A0RI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7d42c89-fdce-43c7-8295-1c0585577208.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RI-10A (Blood Derived Normal), aliquot TCGA-B6-A0RI-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a9401d1-ba2e-4801-9d09-945a888b811b

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 2, Splice Site 2, Intron 1, Frame Shift Ins 1, In Frame Ins 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.6065G>C p.G2022A | Missense Mutation (SNP) | VAF 106/305 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66066115; called by muse, mutect2, varscan2
- CALCA | c.87-1G>A p.X29_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100524104; called by muse, mutect2
- CTCF | c.781+2T>G p.X261_splice | Splice Site (SNP) | VAF 60/86 reads (70%) | catalogued as COSV50462206, COSV50472021; called by muse, mutect2, varscan2
- CYRIB | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67830098; called by muse, mutect2, varscan2
- GIMAP5 | c.834G>C p.L278F | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100500297; called by muse, mutect2
- IL21 | c.206C>A p.T69K | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs752777569, COSV52645943; called by muse, mutect2, varscan2
- PKN2 | c.2881C>T p.R961* | Nonsense Mutation (SNP) | VAF 38/137 reads (28%) | catalogued as rs1314658560, COSV65142839; called by muse, mutect2, varscan2
- SPEN | c.10166C>G p.S3389C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs528449671, COSV65269591; called by muse, mutect2, varscan2
- THOC2 | c.465C>G p.L155= | Splice Region (SNP) | VAF 73/174 reads (42%) | catalogued as rs374192513, COSV99834067; called by muse, mutect2, varscan2
- USP36 | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs140856412; called by muse, mutect2, varscan2
- UTP20 | c.3392C>T p.S1131L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV55376776; called by muse, mutect2, varscan2
- MAP2K4 | c.796_802del p.C266Hfs*8 | Frame Shift Del (DEL) | VAF 57/119 reads (48%) | called by mutect2, pindel, varscan2
- OR56B4 | c.521_523dup p.Y174dup | In Frame Ins (INS) | VAF 104/357 reads (29%) | called by mutect2, pindel, varscan2
- SLC26A4 | c.1902dup p.E635Rfs*9 | Frame Shift Ins (INS) | VAF 52/161 reads (32%) | called by mutect2, pindel, varscan2
- TBX3 | c.743dup p.Y248* (on ENST00000257566 / NM_016569.4; = p.Y228* on NM_005996.4) | Nonsense Mutation (INS) | VAF 54/171 reads (32%) | called by mutect2, pindel, varscan2
- FTMT | c.156C>T p.A52= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV58420201; called by mutect2, varscan2
- LRBA | c.6672G>A p.E2224= | Silent (SNP) | VAF 75/247 reads (30%) | catalogued as COSV63954817; called by muse, mutect2, varscan2
- SPART | c.1623A>C p.V541= | Silent (SNP) | VAF 148/470 reads (31%) | catalogued as COSV62085154; called by muse, mutect2, varscan2
- GCK | c.46-5658G>C | Intron (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100596520; called by muse, mutect2, varscan2
